Somatic mutation profile of tumor specimen TCGA-B6-A40C-01A (aliquot TCGA-B6-A40C-01A-11D-A23C-09) from TCGA case TCGA-B6-A40C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.6 years (18,852 days).
Specimen TCGA-B6-A40C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 417cb11b-63a8-45c2-bf13-b10acf15671e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A40C-10A (Blood Derived Normal), aliquot TCGA-B6-A40C-10A-01D-A23C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf10fff5-7594-425d-9f7d-e8422f55e97c

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 45/87 reads (52%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- BTNL8 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV51458180; called by muse, mutect2, varscan2
- CCK | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377413820; called by muse, mutect2, varscan2
- CDKAL1 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51182321; called by muse, mutect2, varscan2
- CLASP2 | c.4140G>A p.V1380= (on ENST00000359576; = p.V1379= on NM_015097.3 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as rs978090463, COSV56280544; called by muse, mutect2, varscan2
- GATA3 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60517467; called by muse, mutect2, varscan2
- GPR139 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1314429704, COSV58502491; called by muse, mutect2, varscan2
- GPR161 | c.1322A>G p.K441R | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV54789499; called by muse, mutect2, varscan2
- KRT14 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV51421028; called by muse, mutect2, varscan2
- LAMB3 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs202096620, COSV61916421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIN9 | c.485C>G p.T162R (on ENST00000366808 / NM_001270410.2; = p.T107R on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.142); catalogued as COSV60244700, COSV60246245; called by muse, mutect2, varscan2
- MUC17 | c.2561G>A p.S854N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV60286051; called by muse, mutect2, varscan2
- NID1 | c.2639C>A p.A880E | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51618656; called by muse, mutect2, varscan2
- OR5L2 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65723611; called by muse, mutect2, varscan2
- PIH1D1 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51806797; called by muse, mutect2, varscan2
- R3HDM2 | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs1460168077, COSV61287637; called by muse, mutect2, varscan2
- RGS7 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV58536646, COSV58537594; called by muse, mutect2, varscan2
- SACS | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs1463532455, COSV66538534; called by muse, mutect2, varscan2
- SIM2 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as rs534777844, COSV51767683; called by muse, mutect2
- SLC8A1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.346); catalogued as COSV60477579; called by mutect2, varscan2
- TEX15 | c.3018dup p.A1007Sfs*3 (on ENST00000256246; = p.A1390Sfs*3 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 24/53 reads (45%) | catalogued as rs753315680; called by mutect2, varscan2
- TRIM13 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53948971; called by muse, mutect2, varscan2
- TTC3 | c.5686G>A p.D1896N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV61289315; called by muse, mutect2, varscan2
- WDFY3 | c.7297G>A p.V2433I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201478367, COSV55698988; called by muse, mutect2, varscan2
- ZC2HC1A | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV55668214; called by muse, mutect2, varscan2
- HOXB2 | c.27dup p.G10Wfs*156 | Frame Shift Ins (INS) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- ADNP2 | c.957C>A p.L319= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV51538109; called by muse, mutect2, varscan2
- GPR101 | c.504C>T p.Y168= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs755317343, COSV53238432; called by muse, mutect2, varscan2
- LIX1 | c.192T>C p.P64= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV57206749; called by muse, mutect2, varscan2
- MFSD6 | c.1537C>T p.L513= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1219815704, COSV99855254; called by muse, varscan2
- SLITRK4 | c.1077G>A p.V359= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV62023291; called by muse, mutect2, varscan2
- SORBS2 | c.2256G>A p.P752= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs779111898, COSV52997282; called by muse, varscan2
- SPTA1 | c.6675C>T p.D2225= | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as rs186647435, COSV63749286; called by muse, mutect2, varscan2
- TBC1D9B | c.2049C>T p.S683= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1053930071, COSV62281670; called by muse, mutect2, varscan2
- TUBB4A | c.261G>A p.P87= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs974768199, COSV51153611; called by muse, mutect2, varscan2
